Somatic mutation profile of tumor specimen TARGET-10-PARGLE-09A (aliquot TARGET-10-PARGLE-09A-01D) from TARGET case TARGET-10-PARGLE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,183 days).
Specimen TARGET-10-PARGLE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e68eb517-d7a1-428b-9d1e-92c21955cf20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGLE-10A (Blood Derived Normal), aliquot TARGET-10-PARGLE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/583e4ee2-e827-4c2d-97bf-025b934390cc

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 24/35 reads (69%) | catalogued as COSV59316567, COSV59319474; called by muse, mutect2, varscan2
- ANKRD52 | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
